Somatic mutation profile of tumor specimen TCGA-ET-A3DT-01A (aliquot TCGA-ET-A3DT-01A-11D-A19J-08) from TCGA case TCGA-ET-A3DT, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 24.0 years (8,761 days).
Specimen TCGA-ET-A3DT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e1bb243a-1b53-4f2e-84fc-0c34bb8f5ec7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ET-A3DT-10A (Blood Derived Normal), aliquot TCGA-ET-A3DT-10A-01D-A19M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0ca052eb-f920-4629-8e7c-e9ec6ed5e944

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 2, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- GRM2 | c.643G>T p.D215Y | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56583667; called by muse, mutect2, varscan2
- LSP1 | c.726C>T p.G242= | Silent (SNP) | VAF 8/110 reads (7%) | catalogued as COSV61133080; called by muse, mutect2
- NCOR1 | c.4182A>T p.S1394= | Silent (SNP) | VAF 23/89 reads (26%) | catalogued as COSV51965889; called by muse, mutect2, varscan2
